CCDI case PBCKKP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/32439bc8-2c30-4dc7-8593-76cc40a6af7c

Demographics
Sex at birth: male.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 13.3 years (4,845 days).

Biospecimens (3 samples)
- Sample 0DU7ZS: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DU809: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DU81E: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
